Somatic mutation profile of tumor specimen 0DUB88 from CCDI case PBCKLC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 17.0 years (6,227 days).
Specimen 0DUB88: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fea7e87-611f-49b6-9191-db9117eda6b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB69 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009d4323-eb07-4d04-a3c2-1e3d072eacf3

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Intron 2, Silent 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRID2IP | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as rs1037440316, COSV70692209; called by muse, varscan2
- SYNE2 | c.18397_18399del p.E6133del | In Frame Del (DEL) | VAF 48/206 reads (23%) | catalogued as rs1567649807; called by pindel, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 10/102 reads (10%) | called by muse, varscan2
- CYLC2 | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- FBRSL1 | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- PTCHD3 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, varscan2
- ZFC3H1 | c.5632C>T p.L1878F | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- RAD54L2 | c.2811C>T p.Y937= | Silent (SNP) | VAF 28/108 reads (26%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, varscan2
- CCDC144A | c.1715+70A>C | Intron (SNP) | VAF 13/110 reads (12%) | called by muse, varscan2
- PRDX6 | c.-7C>G | 5'UTR (SNP) | VAF 54/154 reads (35%) | catalogued as rs752923989; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
